Gene-level copy-number profile of tumor specimen TCGA-PK-A5H8-01A from TCGA case TCGA-PK-A5H8, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 42.1 years (15,373 days).
Specimen TCGA-PK-A5H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a0b21d4b-11a1-446a-9bef-87ef46dd8c28.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-PK-A5H8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/6d341834-071c-4ecc-9c03-a47fc498d372

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 619; copy number 1: 1,486; copy number 2: 33,393; copy number 3: 5,220; copy number 4: 18,073; copy number 5: 102; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr9:41,979,352–42,668,887, 18 genes: CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr9:64,369,394–64,637,586, 10 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr13:52,488,993–52,587,095, 2 genes: AL137058.1, AL137058.3.
- chr15:20,282,744–20,599,195, 9 genes: CHEK2P2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P.
- chr15:20,759,311–20,826,173, 5 genes: AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5.
- chr15:20,901,441–21,946,641, 57 genes: ZNF519P2, NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P, IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16, NBEAP4, AC068446.1, AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 104 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:70,219,918–71,259,238, 19 genes, copy number 5: GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP, GTF2H2, OCLNP1, NAIPP4, CDH12P4, GUSBP9, GUSBP17.
- chr7:76,818,377–76,919,191, 2 genes, copy number 6: AC006972.1, AC007003.1.
- chr7:142,407,672–142,813,399, 67 genes, copy number 5 (broad region; genes not listed).
- chr16:14,632,931–14,669,236, 1 gene, copy number 5 (within-gene range 4–5): BFAR.
- chr16:14,672,548–14,902,174, 11 genes, copy number 5 (within-gene range 3–5): PLA2G10, AC009167.1, NPIPA3, AC136443.1, AC136443.4, NPIPA2, AC136443.2, ABCC6P2, NOMO1, AC136443.5, AC136443.3.
- chr16:14,907,717–14,911,345, 2 genes, copy number 5 (within-gene range 3–5): MIR3670-1, AC138932.1.
- chr16:14,911,551–14,935,708, 1 gene, copy number 5 (within-gene range 3–5): PKD1P3.
- chr16:14,922,802–14,952,060, 1 gene, copy number 5 (within-gene range 3–5): NPIPA1.

Autosomal genes at a single copy (total copy number 1): 1,486. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
